Gene-level copy-number profile of tumor specimen TCGA-LN-A4A9-01A from TCGA case TCGA-LN-A4A9, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 58.1 years (21,217 days).
Specimen TCGA-LN-A4A9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.4f8f5406-56e2-4968-a7ba-3013ac0c447a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4A9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f106cc8f-9f84-4343-88e0-2982e51210fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 3,794; copy number 2: 39,371; copy number 3: 12,502; copy number 4: 3,659; copy number 5: 127; copy number 6: 42; copy number 7: 131; copy number 8: 6; copy number 9: 61; copy number 12: 66; copy number 17: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A4A9-01A-11D-A28A-01): tumor purity 0.73, ploidy 2.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:103,926,567–103,927,806, 1 gene: AL136455.1.
- chr2:212,581,357–213,021,545, 7 genes: AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.
- chr3:25,324,174–25,352,392, 2 genes: CFL1P7, RNA5SP126.
- chr3:54,874,605–55,300,738, 5 genes (within-gene range 0–2): CACNA2D3-AS1, LRTM1, AC092059.1, LINC02017, LINC02030.
- chr7:27,733,064–27,844,564, 2 genes (within-gene range 0–2): TAX1BP1-AS1, TAX1BP1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr13:48,134,358–48,303,661, 3 genes: POLR2KP2, ITM2B, RB1-DT.
- chr13:48,316,863–48,341,330, 3 genes: PPP1R26P1, PCNPP5, AL392048.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 443 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,383,838–43,705,518, 170 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:47,688,463–48,182,428, 9 genes, copy number 7 (within-gene range 3–7): LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2.
- chr1:58,047,889–63,317,274, 76 genes, copy number 12–17 (within-gene range 3–17) (broad region; genes not listed).
- chr4:164,597,719–164,726,706, 3 genes, copy number 5: AC074198.1, RNU6-284P, CHORDC1P3.
- chr5:2,184,710–4,874,759, 25 genes, copy number 5–7: Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1.
- chr5:6,839,460–7,219,291, 1 gene, copy number 6 (within-gene range 4–6): LINC02196.
- chr5:7,047,227–7,391,907, 13 genes, copy number 6: RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142.
- chr5:8,785,042–9,903,852, 19 genes, copy number 5–7: AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr5:13,144,000–13,250,662, 2 genes, copy number 6: AC016553.1, RPS23P5.
- chr5:21,882,585–22,213,761, 4 genes, copy number 6: HSPD1P1, AC139497.1, PMCHL1, AC138854.1.
- chr5:23,262,159–23,528,093, 6 genes, copy number 6 (within-gene range 3–6): AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.
- chr5:23,951,348–24,353,443, 7 genes, copy number 5: C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr5:34,656,328–34,832,612, 1 gene, copy number 5 (within-gene range 2–6): RAI14.
- chr5:37,939,365–37,966,964, 3 genes, copy number 5: AC008869.1, LINC02110, AC034226.1.
- chr6:43,629,540–44,527,448, 33 genes, copy number 5: MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1.
- chr6:57,314,805–58,438,364, 16 genes, copy number 6: PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr14:51,253,933–51,436,963, 6 genes, copy number 8: Y_RNA, LINC00519, LINC00640, AL358332.1, LINC02310, SETP2.
- chr20:33,161,768–34,347,785, 42 genes, copy number 5: BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1.
- chr20:34,384,165–34,442,025, 3 genes, copy number 5: Y_RNA, CDC42P1, ITCH-AS1.
- chr20:39,213,777–39,349,392, 4 genes, copy number 5: LINC01734, AL035251.1, ATG3P1, RN7SL680P.

Autosomal genes at a single copy (total copy number 1): 2,324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
